Surgical pathology report (de-identified scan), TCGA case TCGA-US-A774, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Garvan Institute of Medical Research, specimen TCGA-US-A774-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Adenocarcinoma, duct
Site ^{C&E} Pancreas head 8500/3
^{path} C25.0
Pancreas head & uncinate process C25.0
on 8/20/13 Lab No

Received

SPECIMEN TYPE: Whipples

CLINICAL NOTES:

Ca uncinat process of pancreas. Whipple procedure. Pancreatic ca whipple procedure. 1. perISMA neural tissue. 1. Station 8A lymph node. 2) Aortocaval lymphatic tissue.

FROZEN SECTION OPINION: Adenocarcinoma 40mm is present. Neck margin is clear of tumour. message to

MACROSCOPIC:

Specimen received in four jars.

A)

SYNOPTIC REPORT FOR WHIPPLE'S RESECTION

MACROSCOPIC:

Specimen labelled: Whipple's.

Specimen Type:

Pancreaticoduodenectomy (Whipple's resection), partial pancreatectomy

Specimen dimensions:

Length of duodenum: 110mm

Length of lesser curve of stomach: 50mm

Length of greater curve of stomach: 55mm

Size of gallbladder: The distended gallbladder measures 120 mm in length and 80mm in open circumference with a wall thickness of 2 mm. On cut section the mucosa is congested with the lumen containing blood clot. The cystic duct measures about 30mm in length.

Wall thickness of gallbladder: 2mm

Calculi in gallbladder: Nil.

Size of and weight of spleen: Not included with specimen.

Length of bile duct: 40mm.

Maximum diameter of bile duct: 20mm.

Size of pancreas: 70 x 50 x 50mm.

Location of stent: No stent is identified.

Tumour location: Head of pancreas and uncinate process

Tumour:

Configuration: The tumour is well circumscribed, firm and infiltrating into the

COPIES

Page 1 of 4

A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

[page 2 of 4]
Lab No

SPECIMEN TYPE: Whipples

underlying pancreatic tissue. The overlying mucosa over the tumour appears intact. The tumour is pale grey and firm in consistency. There is no evidence of any necrosis or haemorrhage.

Tumour Size:

Greatest dimension: 40mm

*Additional dimensions: 30 x 20mm

Distance of tumour to margins:

Pancreatic neck: 20mm

Periuncinate soft tissue: 1mm

Posterior retroperitoneal: 2mm

Portal vein bed: 1mm

Anterior pancreatic capsule: 20

Common bile duct: 20mm

Proximal intestinal/gastric: 90mm

Distal intestinal margin: 70mm

Proximal pancreatic margin (applicable to distal pancreatectomies only): N/A

Additional gross pathologic findings: No other distinctive lesions identified in the pancreas or in the stomach and intestine.

The portal vein bed is inked green, the periuncinate margin is inked red. The true posterior margin is inked blue and the true anterior margin is inked blue.

Block 1 - common bile duct margin

Block 2 - distal duodenum margin

Block 3 - proximal gastric margin

Block 4 - tumour

Blocks 5 to 8 - tumour with overlying uncinate margin

Blocks 9 to 11 - tumour with portal vein bed

Block 12 - tumour with anterior margin

Blocks 13 to 15 - posterior margin

Block 16 - tumour with overlying duodenum mucosa

Blocks 17 and 18 - gallbladder

Block 17 - representative section from the proximal end and body

Block 18 - representative section from the fundus

Block 19 - single node bisected

Blocks 20 and 21 - single node largest node bisected

Block 22 - two lymph nodes

Block 23 - three lymph nodes dissected

Block 24 - single node

COPIES

Page 2 of 4

[page 3 of 4]
Received

Lab No

SPECIMEN TYPE: Whipples

Block 25 - single node

Blocks 26 - 29 - Pancreatic neck margin sampled in frozen section

B) 'peri SMA neural tissue'. The specimen consists of two pieces of soft tissue each measuring 10mm in diameter.

C) '8A lymph node'. The specimen consists of fibrofatty piece of tissue with lymph node measuring 25 x 20 x 5mm. The largest node measures 15 x 10 x 5mm. Two additional smaller nodes dissected and rest of the fibrofatty tissue embedded in block 2.

D) 'Aortocaval lymph node'. The specimen consists of fibrofatty piece of tissue aggregating to 25mm in diameter. All embedded in two blocks 1 and 2.

MICROSCOPIC:

A-D)

SYNOPTIC REPORT FOR WHIPPLE'S RESECTION:

Tumour location: Uncinate process and Head of Pancreas

Histologic type (WHO classification): Adenocarcinoma

Histologic grade (TNM grading system): G3 (poorly differentiated)

Tumour size: 40 mm.

Extension out of pancreas: Present

Small vessel (capillary/lymphatic) invasion: Present

Large vessel (vein/artery) invasion: Absent

Perineural invasion: Present

Perineural invasion of retroperitoneal (periuncinate) neural plexus: Present

Distance of invasive tumour from resection margins:

Pancreatic neck: 20mm

Periuncinate soft tissue: 1.2mm

Posterior retroperitoneal: 2.5mm

Portal vein bed: 1mm

Common bile duct: 20mm

Lymph nodes from main resection specimen:

Metastatic carcinoma is present in 2 of 11 lymph nodes from the main resection specimen.

Separately received lymph nodes:

COPIES	
	Page 3 of 4

[page 4 of 4]
Received

Lab No

SPECIMEN TYPE: Whipples

Specimen B (peri-SMA tissue): There is no evidence of malignancy in 1 node
Specimen C (8A nodes): There is no evidence of malignancy in 3 nodes
Specimen D (Aortocaval nodes): There is no evidence of malignancy in 2 nodes

Highest grade of Pan-In present: PanIN3
Grade of Pan-In at pancreatic neck resection margin: Absent

Pathologic Staging (pTNM, AJCC 7th edition 2009)

Staged as: Pancreatic ductal carcinoma

pT: pT3

pN: pN1

Overall stage: p2B

SUMMARY:

Tumour type: Adenocarcinoma
Tumour grade: G3 (poorly differentiated)
Tumour location: Head of pancreas and uncinate process
Tumour size: 40mm
Lymph nodes: Metastatic carcinoma is present in 2 of 17 nodes.
Stage: p2B(T3N1)
Margins:
Carcinoma is 1mm from the portal vein bed margin and 1.2mm from the periuncinate margin.

REPORTING PATHOLOGIST:

(Electronic Signature)

COPIES

Source: NCI Genomic Data Commons file eed7a7b1-c8cd-46e6-a6c4-76fef74bf904 (TCGA-US-A774.4E5397E1-3584-4F5F-80FB-126A46B9FD73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).